HCMI case HCM-BROD-0450-C15 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Esophagus. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b35898b6-7e8a-43a9-b6f2-4dfc91255e26

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1965; Vital status: Dead; Days to death: 452 days (1.2 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C76.2; Tissue or organ of origin: Esophagus, NOS; Site of resection or biopsy: Abdomen, NOS; Classification of tumor: primary; Age at diagnosis: 52.4 years (19,140 days); AJCC staging edition: 8th; AJCC clinical stage: Stage IIIA; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M0; Prior malignancy: no; Prior treatment: Yes; Esophageal columnar metaplasia present: No; Goblet cells columnar mucosa present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel + Fluorouracil + Leucovorin + Oxaliplatin; Treatment intent type: Neoadjuvant; Days to treatment start: 38 days.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 112 days.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Pembrolizumab; Treatment intent type: Neoadjuvant; Days to treatment start: 192 days.
   Treatment given: Treatment type: Targeted Molecular Therapy; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 287 days; Days to treatment end: 413 days (1.1 years).
   Recorded as not given: adjuvant Chemotherapy, for residual disease; adjuvant Immunotherapy (Including Vaccines), for residual disease; neoadjuvant Radiation Therapy, NOS; adjuvant Radiation Therapy, NOS, for residual disease.

Follow-up (2 entries)
- Days to follow up: 112 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Abdomen, NOS; Days to progression: 112 days.
- Follow-up contacts recording only the day: day 378, day 452.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 53 kg; Height: 172 cm; BMI: 18.
- Timepoint category: Prior to Diagnosis; Risk factors: GERD.

Exposures
- Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Alcohol intensity: Occasional Drinker.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (2 samples)
- Sample HCM-BROD-0450-C15-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-BROD-0450-C15-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
